Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94N, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94N-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

ICD O-3
Mixed germ cell tumor
9061/3
Site R Testis NOS
C62.9
JW 3/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

1. "Right testis":

- Mixed germ cell tumor (endodermal sinus tumor – 60%; embryonal carcinoma – 30% and seminoma – 10%) with extensive necrosis.
- Neoplasia size: 8.0 x 5.0 x 1.0cm.
- Sanguineous vascular invasion: not detected.
- Lymphatic vascular invasion: not detected.
- Perineural invasion: not detected.
- Rete testis: compromised by the neoplasia.
- Tunica albuginea: compromised by the neoplasia, infiltrating up to adjacent adipose tissue with uninvolved margins.
- Epididymis: involved by neoplasia.
- Spermatic cord: uninvolved by neoplasia.
- Adjacent testicular parenchyma: focal atrophy.
- Spermatic cord margin: uninvolved by neoplasia.

Source: NCI Genomic Data Commons file 6f004ce5-b11b-4b5f-bae1-133a6a66a5c0 (TCGA-YU-A94N-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).